Surgical pathology report (de-identified scan), TCGA case TCGA-76-6280, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6280-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-76-6280

FINAL DIAGNOSIS:

1. Left frontal brain tumor: GLIOBLASTOMA MULTIFORME, WHO GRADE IV.
SEE MICROSCOPIC DESCRIPTION.
2. Left frontal brain tumor: GLIOBLASTOMA MULTIFORME, WHO GRADE IV.
SEE MICROSCOPIC DESCRIPTION.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Abundant endothelial proliferation is present in the tumor. Foci of tumor necrosis are identified on slides 1B and 2A.

Frozen Section Diagnosis:

1. High-grade malignant glioma, consistent with glioblastoma

Clinical History and Diagnosis:

Left frontal brain tumor

Source of Specimen:

- 1: Left frontal brain tumor
- 2: Left frontal brain tumor

Gross Description:

- [REDACTED]
1. Left frontal brain tumor: Received fresh for frozen section are

[page 2 of 2]
multiple fragments of red-tan, soft tissue measuring 2.0 x 1.5 x 0.7 cm in aggregate. Touch preparation slides are created and one half of the specimen is submitted in one cassette for frozen section. The remainder of the specimen is entirely submitted in one cassette for permanent section.

Designations:

- A. frozen section control
- B. remainder of specimen

2. Left frontal brain tumor: Received in formalin is a single fragment of red-tan, soft tissue measuring 0.7 x 0.3 x 0.3 cm. The specimen is entirely submitted in one cassette.

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file 8fcd0aad-9605-4d50-8f7c-5967eb44e8b7 (TCGA-76-6280.6C77527E-B771-4544-BD9A-8468F2FF593E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).